Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PH, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PH-01A (Primary Tumor).

[page 1 of 2]
Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

per TSS, 100% tubular

I - "Stomach - omentum":

Moderately differentiated adenocarcinoma, mixed type of Lauren.

Ultero-infiltrative lesion, measuring 8.0 cm in major axis, involving until the serosa.

Presence of lymphatic and perineural infiltration.

Spiculated growing pattern, moderate peritumoral inflammatory infiltrate.

Surgical margins uninvolved by neoplasia.

Adjacent mucosa with active, moderate chronic pangastritis, with incomplete intestinal metaplasia.

Metastatic carcinoma in 10 of 12 (10/12) lymph nodes dissected from the lesser curvature and 11 of 14 lymph nodes dissected from the greater curvature.

Presence of capsular infiltration with transposition, without conglomerates.

Omentum uninvolved by neoplasia.

Iii - "Celiac trunk lymph node":

Metastatic carcinoma in 3 of the 7 lymph nodes dissected (3/7).

*CCRF ICD-O-3
Adenocarcinoma tubular 8211/3
path
Adenocarcinoma w/mixed cell
Type 8255/3
Site: Gastric antrum C16.3
JW 3/7/14*

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Mixed Type of Lauren	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Tubular (intestinal type)	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on Top Slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Per TSS, dx discrepancy from states TCGA tumor to be adenocarcinoma, tubular. BCR

Diagnosis Discrepancy	100% tubular	☒
TI/FAA Discrepancy		☒
Qual/Syncronous Primary Sites		☒

Source: NCI Genomic Data Commons file 05cfad65-2ed6-41d6-898c-3f0d6e0f751b (TCGA-VQ-A8PH.9BFB73D5-8934-4601-937F-FBB0A6E0E781.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).